Somatic mutation profile of tumor specimen TCGA-Q1-A73S-01A (aliquot TCGA-Q1-A73S-01A-11D-A33O-09) from TCGA case TCGA-Q1-A73S, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenosquamous carcinoma; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 33.5 years (12,229 days).
Specimen TCGA-Q1-A73S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1acf0da-3887-41d0-ad33-b25f0374ee15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Q1-A73S-10B (Blood Derived Normal), aliquot TCGA-Q1-A73S-10B-01D-A33O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3d072de-3d16-47c7-bdb2-ed0f9f4d6196

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, 3'UTR 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO7 | c.1247G>A p.R416Q (on ENST00000274979; = p.R362Q on NM_001370694.2) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.15); catalogued as rs373704127; called by muse, mutect2, varscan2
- ATP1A3 | c.94C>T p.R32C (on ENST00000545399 / NM_001256214.2; = p.R19C on NM_152296.5) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs782229302, COSV57487195; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- BANK1 | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 31/39 reads (79%) | catalogued as rs187331023, COSV100536000; called by muse, mutect2, varscan2
- CEACAM18 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs267605617; called by muse, mutect2, varscan2
- CHM | c.1727C>G p.S576C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs780111922, COSV63302714; called by muse, mutect2, varscan2
- CIB2 | c.360C>A p.D120E | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51949007; called by muse, mutect2, varscan2
- FBXO46 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV58347980; called by muse, mutect2, varscan2
- KCNH7 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100037343, COSV59802061; called by muse, mutect2, varscan2
- MTUS2 | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as COSV70917833; called by muse, mutect2, varscan2
- SETMAR | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.066); catalogued as rs761457087, COSV62781074; called by muse, mutect2, varscan2
- TYRO3 | c.1235C>A p.S412Y | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.689); catalogued as COSV55484488; called by muse, mutect2, varscan2
- ZNF273 | c.1154A>T p.Q385L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.096); catalogued as COSV60399244; called by muse, mutect2, varscan2
- RB1 | c.1939_1940del p.L647Ffs*5 | Frame Shift Del (DEL) | VAF 27/72 reads (38%) | called by pindel, varscan2
- INPP5D | c.2661C>T p.H887= (on ENST00000445964 / NM_001017915.3; = p.H886= on NM_005541.5) | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as rs768413369, COSV64038167; called by muse, mutect2, varscan2
- IQGAP1 | c.4443G>A p.L1481= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs199804766, COSV99184897; called by muse, mutect2, varscan2
- SLC12A5 | c.927C>A p.I309= (on ENST00000454036 / NM_001134771.2; = p.I286= on NM_020708.5) | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as COSV54796354; called by muse, mutect2, varscan2
- SPTBN5 | c.9558G>A p.Q3186= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV58023415; called by muse, mutect2, varscan2
- TNS3 | c.1432C>T p.L478= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV60793746; called by mutect2, varscan2
- UNC45A | c.1182T>C p.L394= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as COSV67816718; called by muse, mutect2, varscan2
- GPR17 | c.*2C>T | 3'UTR (SNP) | VAF 16/58 reads (28%) | catalogued as rs372407392; called by muse, mutect2, varscan2
